Surgical pathology report (de-identified scan), TCGA case TCGA-5K-AAAP, project TCGA-THYM (Thymoma), tissue source site St. Joseph's Hospital AZ, specimen TCGA-5K-AAAP-01A (Primary Tumor).

ICD-0.3
Thymoma, type A, NOS, malignant
8581/3
Thymoma, spindle cell (type A)
malignant 8581/3
Site: Thymus C379
Mediastinum C383
5/10/14

Addendum Microscopic Description:

Additional sections have been reviewed and the case has been consulted with Drs. All reviewers agree with the initial interpretation. The process is an invasive thymoma. Based on the macroscopic involvement of the pericardium (clinically) and the invasion of the pleura, the process would be considered stage III. The resection margins appear negative.

Addendum Diagnosis:

Thymus and lung, resection: Invasive Thymoma.

Invasion: Present (Microscopically invasive of pleura; macroscopically invasive of pericardium per op report). Approximately 8.5cm. Spindle cell (WHO A). Degree of cytologic Atypia: Mild. Vascular Invasion: Not identified. Resection Margins: Negative for diagnostic neoplasm.

Microscopic Description:

Sections of mediastinal tissue demonstrate a thymoma. The neoplasm is arranged as lobulated nests of spindled cells, divided by fibrous bands of varying thickness. There is no significant cytologic atypia and mitotic figures are few. There is extension into the pleura. No definitive lymphovascular invasion is appreciated. The neoplasm demonstrates zones of infarct/necrosis, as well as lobulated hyalinization. The inked peripheral resection margin and pulmonary resection margin are negative for diagnostic neoplasm. Per operative note, there was extension of the lesion into the pericardium as well. Additional sections are pending.

Pathological Diagnosis (provisional):

Thymoma- Invasion-present (microscopically invasion of pleura, macroscopically invasive of pericardium per operative report)- additional sections pending. Maximal Tumor Dimension- Approx 8.5cm Histologic Type: Spindle cell (who A). Degree of Cytologic Atypia- Mild. Vascular Invasion- Not identified. Resection Margins- Negative for diagnostic neoplasm.

Source: NCI Genomic Data Commons file 2db2a922-b151-4797-9f9e-24a79d8b74a1 (TCGA-5K-AAAP.73A5B98F-EF2E-436C-ACEF-05622F89C73A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).